Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GN, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GN-06A (Metastatic).

[page 1 of 2]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- A) PORTAL HEPATIC LYMPH NODE:
One lymph node, negative for melanoma (0/1).
- B) PROXIMAL JEJUNAL MESENTERIC LYMPH NODE:
One lymph node, see addendum report..
- C) GALLBLADDER, CHOLECYSTECTOMY:
Acute cholecystitis and serositis.
Negative for melanoma.
- D) DUODENUM, RESECTION:
METASTATIC MALIGNANT MELANOMA (50 x 25 and 19 x 15 mm).
Margins of resection free of melanoma.

ICD-O-3
Melanoma NOS 8720/3
Date: Small intestine 017.9
Duodenum 017.0
JW 11/27/13

Entire report and diagnosis completed by

GROSS DESCRIPTION

- (A) PORTAL HEPATIC LYMPH NODE - A fragment of pink-tan tissue (2.0 x 1.0 cm). The specimen is serially sectioned and submitted in toto in A.
- (B) PROXIMAL JEJUNAL MESENTERIC LYMPH NODE - A single lymph node (0.5 x 0.5 x 0.3 cm). The specimen is bisected and submitted in its entirety for intraoperative frozen section in one block labeled B.
*FS/DX: ONE LYMPH NODE, NEGATIVE FOR METASTATIC MELANOMA.
- (C) GALLBLADDER - An intact gallbladder measuring 9.0 cm in length and 5.0 cm in maximum circumference. The bile is dark-green. The mucosa is pink-green. The wall of the gallbladder is 0.2 cm in thickness. No gall stones are present.
SECTION CODE: C1, bile duct; C2, representative sections of the gallbladder.
- (D) RESECTION OF DUODENUM - A segment of small intestine (17.0 cm in length x 2.5 cm in diameter). The specimen is oriented by the surgeon.
There are two tan fleshy hemorrhagic nodules (5.0 x 2.5 x 2.5 cm and 1.9 x 1.5 x 1.0 cm) which protrude into the lumen of the small intestine. The larger nodule is 5.0 cm from the nearest proximal margin and the small nodule is 0.5 cm from the nearest proximal margin. Both nodules are associated with serosal and wall puckering.
The remainder of the small intestinal mucosa is grossly unremarkable.
INK CODE: Black - serosa underlying tumor; yellow - proximal margin.
SECTION CODE: D1, distal margin en face; D2 and D3, representative sections of proximal margin, perpendicular sections; D4 and D6, representative sections of large tumor.

CLINICAL HISTORY

None given.

SNOMED CODES

T-C4000, M-00110, T-59000, M-87206

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

Start of ADDENDUM

[page 2 of 2]
ADDENDUM

Addendum completed by

DIAGNOSIS

B: Examination of an immunohistochemical study on paraffin sections with a cocktail (HMB45 and anti-MART1) fails to reveal metastatic melanoma.

Released by:

-----END OF REPORT-----

Diagnostic Discrepancy		☒

Source: NCI Genomic Data Commons file 8709a1e2-fa12-4815-a6c2-275de008c6aa (TCGA-D3-A8GN.13164D83-422C-4C2B-95DB-3F9F075F9F9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).